Somatic mutation profile of tumor specimen MP2PRT-PAVTWD-TMP1-A (aliquot MP2PRT-PAVTWD-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVTWD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,552 days).
Specimen MP2PRT-PAVTWD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a5457d1-17b2-4784-a01b-f656ea633369.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTWD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTWD-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/833c36da-dffc-4310-b6f0-cad63c7d4dfc

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Frame Shift Ins 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH12 | c.7906C>T p.R2636C (on ENST00000351747; = p.R3504C on NM_001366028.2) | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs759989524, COSV100696692; called by muse, mutect2, varscan2
- DNAH2 | c.12937G>A p.V4313I | Missense Mutation (SNP) | VAF 37/791 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.683); catalogued as rs748420518, COSV66720122; called by muse, mutect2
- DNAH7 | c.6554G>A p.R2185H | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754967966, COSV56763812; called by muse, mutect2
- HSP90AB1 | c.2129dup p.L711Sfs*5 | Frame Shift Ins (INS) | VAF 145/470 reads (31%) | catalogued as rs1223869810; called by mutect2, pindel, varscan2
- PDYN | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 191/476 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376562868; called by muse, mutect2, varscan2
- RSC1A1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs928719800, COSV60779393; called by muse, mutect2
- TMEM132C | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 207/501 reads (41%) | catalogued as rs1244363099, COSV59416276; called by muse, mutect2, varscan2
- CADPS2 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EN1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 179/452 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KDM6A | c.2904_2905insACCA p.V969Tfs*11 | Frame Shift Ins (INS) | VAF 123/283 reads (43%) | called by mutect2, pindel, varscan2
- MROH2B | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAXIP1 | c.896T>A p.V299D | Missense Mutation (SNP) | VAF 140/423 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS1 | c.4102C>A p.Q1368K | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, varscan2
- SPATC1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.319); called by muse, varscan2
- ANKRD13B | c.1449C>T p.F483= | Silent (SNP) | VAF 175/772 reads (23%) | catalogued as rs1336820028; called by muse, mutect2, varscan2
- COL6A3 | c.8583C>T p.N2861= | Silent (SNP) | VAF 153/331 reads (46%) | catalogued as rs375994186; called by muse, mutect2, varscan2
- DNAH5 | c.11208G>A p.K3736= | Silent (SNP) | VAF 93/241 reads (39%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.645C>T p.Y215= | Silent (SNP) | VAF 113/340 reads (33%) | catalogued as rs1245445796, COSV57107574, COSV57108980; called by muse, mutect2, varscan2
- SGTA | c.138G>A p.T46= | Silent (SNP) | VAF 132/394 reads (34%) | catalogued as rs774035487; called by muse, mutect2, varscan2
- STK32B | c.180C>T p.I60= | Silent (SNP) | VAF 170/465 reads (37%) | catalogued as rs531366468; called by muse, mutect2, varscan2
- ZNF251 | c.789A>G p.K263= | Silent (SNP) | VAF 241/625 reads (39%) | catalogued as COSV52957754; called by muse, mutect2, varscan2
- IGKV3D-20 | chr2:90039479 ins C | 3'Flank (INS) | VAF 58/193 reads (30%) | called by pindel, varscan2*
